Somatic mutation profile of tumor specimen HCM-BROD-0199-C71-01A (aliquot HCM-BROD-0199-C71-01A-11D-A786-36) from HCMI case HCM-BROD-0199-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.1 years (17,924 days).
Specimen HCM-BROD-0199-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5edee6a7-53e4-43fe-8b49-c665efdc548b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0199-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0199-C71-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5abf6adc-484f-44b6-9939-9e01e6bff2c6

The open-access MAF lists 56 somatic variants for this specimen: 34 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 18, Nonsense Mutation 4, Intron 2, 5'UTR 1, Splice Site 1, 3'UTR 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 150/501 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs377737331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD163L1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs139153315; called by muse, mutect2, varscan2
- CD209 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 99/374 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139712001; called by muse, mutect2, varscan2
- DNAI1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 50/753 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs752354598, COSV54280364, COSV54280621; called by muse, mutect2
- DROSHA | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 96/341 reads (28%) | catalogued as COSV60781622; called by muse, mutect2, varscan2
- ESPNL | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 196/653 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs778024556, COSV54541083; called by muse, mutect2, varscan2
- GRB7 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.532); catalogued as rs201668668; called by muse, mutect2, varscan2
- GRIP1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 38/495 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs367635870; called by muse, mutect2
- LETM1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 113/375 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201510306, COSV57103367; called by muse, mutect2, varscan2
- NLRP3 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 288/983 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as rs199637520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRROS | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 152/477 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs986757744; called by muse, mutect2, varscan2
- PPP3R2 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 161/605 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs1200972717, COSV62455332; called by muse, mutect2, varscan2
- PTEN | c.183T>G p.H61Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64289119, COSV99057944; called by muse, mutect2, varscan2
- REPS2 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58184927; called by muse, mutect2, varscan2
- STIM2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52838637; called by muse, mutect2, varscan2
- TSKS | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.859); catalogued as rs1317673712; called by muse, mutect2, varscan2
- TTC28 | c.2143C>T p.R715* | Nonsense Mutation (SNP) | VAF 71/195 reads (36%) | catalogued as COSV67414832; called by muse, mutect2, varscan2
- UBR4 | c.3617C>G p.S1206C | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs555728639, COSV64382807; called by muse, mutect2, varscan2
- ZNF333 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 82/306 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1240772288; called by muse, mutect2, varscan2
- ZNF831 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 127/432 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64040754; called by muse, mutect2, varscan2
- ANKS1A | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD6 | c.4069G>T p.E1357* | Nonsense Mutation (SNP) | VAF 82/339 reads (24%) | called by muse, mutect2, varscan2
- CPA6 | c.293T>G p.L98* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- DGKI | c.956T>G p.V319G | Missense Mutation (SNP) | VAF 70/393 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DPP4 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EGFR | c.1793_1795del p.G598del | In Frame Del (DEL) | VAF 3008/6546 reads (46%) | called by mutect2, pindel, varscan2
- GRM6 | c.320A>C p.E107A | Missense Mutation (SNP) | VAF 159/512 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PAQR3 | c.349-1G>T p.X117_splice | Splice Site (SNP) | VAF 41/132 reads (31%) | called by muse, mutect2, varscan2
- POLR2A | c.4174T>C p.Y1392H | Missense Mutation (SNP) | VAF 148/518 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RTBDN | c.543C>G p.C181W (on ENST00000393233 / NM_001270444.1; = p.C213W on NM_031429.2) | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VPS13D | c.12159C>A p.F4053L | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ZAP70 | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 163/475 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF462 | c.6174_6175del p.C2059Lfs*7 | Frame Shift Del (DEL) | VAF 64/318 reads (20%) | called by pindel, varscan2
- ZNF708 | c.1640T>G p.L547R | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CILP | c.1767G>A p.L589= | Silent (SNP) | VAF 86/285 reads (30%) | catalogued as COSV99973097; called by muse, mutect2, varscan2
- FLNC | c.5433G>A p.R1811= | Silent (SNP) | VAF 220/1267 reads (17%) | called by muse, mutect2, varscan2
- IGF1 | c.108G>A p.A36= | Silent (SNP) | VAF 171/571 reads (30%) | catalogued as rs371125874; called by muse, mutect2, varscan2
- MAP3K20 | c.1908G>A p.S636= | Silent (SNP) | VAF 90/318 reads (28%) | catalogued as rs112889653; called by mutect2, varscan2
- MATN4 | c.1383C>T p.R461= (on ENST00000372754; = p.R420= on NM_003833.4) | Silent (SNP) | VAF 122/472 reads (26%) | called by muse, mutect2, varscan2
- NCAM2 | c.1134T>C p.Y378= | Silent (SNP) | VAF 58/184 reads (32%) | called by muse, mutect2, varscan2
- OBSCN | c.21444G>A p.A7148= | Silent (SNP) | VAF 69/239 reads (29%) | catalogued as rs375088814; called by muse, mutect2, varscan2
- OR2A5 | c.669G>A p.A223= | Silent (SNP) | VAF 82/1546 reads (5%) | catalogued as rs771031861, COSV68738523; called by muse, mutect2
- PIK3C2G | c.2868C>T p.N956= (on ENST00000676171; = p.N915= on NM_004570.5) | Silent (SNP) | VAF 27/154 reads (18%) | called by muse, mutect2, varscan2
- RNF151 | c.360G>A p.S120= | Silent (SNP) | VAF 176/569 reads (31%) | catalogued as rs374940392, COSV58400005; called by muse, mutect2, varscan2
- RRP1 | c.807C>T p.P269= | Silent (SNP) | VAF 31/127 reads (24%) | catalogued as rs774930391, COSV101513845, COSV101513866; called by muse, mutect2, varscan2
- SCUBE2 | c.855G>A p.T285= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as rs553227629; called by muse, mutect2, varscan2
- SOCS4 | c.225G>A p.E75= | Silent (SNP) | VAF 95/251 reads (38%) | called by muse, mutect2, varscan2
- SPOCD1 | c.867C>T p.P289= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs370591004, COSV57100233; called by muse, mutect2, varscan2
- TAF3 | c.2118G>A p.K706= | Silent (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- TGM7 | c.732C>T p.G244= | Silent (SNP) | VAF 106/327 reads (32%) | catalogued as rs765744133; called by muse, mutect2, varscan2
- TM6SF2 | c.600C>T p.T200= | Silent (SNP) | VAF 53/166 reads (32%) | catalogued as rs748636134; called by muse, mutect2, varscan2
- ZSWIM4 | c.231G>A p.R77= | Silent (SNP) | VAF 208/762 reads (27%) | catalogued as rs1203070982, COSV99584488; called by muse, mutect2, varscan2
- COL1A2 | c.2673+43G>A | Intron (SNP) | VAF 79/512 reads (15%) | catalogued as rs1240782337; called by muse, mutect2, varscan2
- CPLX2 | c.*134G>C | 3'UTR (SNP) | VAF 70/238 reads (29%) | called by muse, mutect2, varscan2
- POMZP3 | c.228-59G>A | Intron (SNP) | VAF 27/451 reads (6%) | catalogued as rs575970926; called by muse, mutect2
- TMEM37 | c.-46G>A | 5'UTR (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
